Somatic mutation profile of tumor specimen TCGA-YL-A8SF-01A (aliquot TCGA-YL-A8SF-01A-11D-A377-08) from TCGA case TCGA-YL-A8SF, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 62.5 years (22,844 days).
Specimen TCGA-YL-A8SF-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d4396b7d-19cb-4754-8081-4a347d237e93.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-YL-A8SF-10A (Blood Derived Normal), aliquot TCGA-YL-A8SF-10A-01D-A37A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6ba9d032-0f9c-47f2-ada0-e48899bc94a4

The open-access MAF lists 18 somatic variants for this specimen: 14 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 14, Silent 4.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BCL9L | c.1123C>T p.P375S | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as COSV99419522, COSV99419531; called by muse, mutect2, varscan2
- CDC5L | c.1196G>A p.R399Q | Missense Mutation (SNP) | VAF 26/76 reads (34%) | SIFT tolerated (0.18); PolyPhen benign (0.041); catalogued as rs370966869; called by muse, mutect2, varscan2
- CGB5 | c.82C>T p.R28W | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT tolerated (0.19); PolyPhen benign (0.013); catalogued as rs1425976710; called by muse, mutect2, varscan2
- CILP | c.645C>G p.D215E | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT tolerated (0.68); PolyPhen benign (0.003); catalogued as COSV99973559; called by muse, mutect2, varscan2
- CPA2 | c.433A>C p.S145R | Missense Mutation (SNP) | VAF 17/78 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.171); catalogued as COSV99744087; called by muse, mutect2, varscan2
- DOCK9 | c.5798G>A p.R1933H (on ENST00000376460 / NM_001366676.2; = p.R1934H on NM_015296.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1052569622, COSV100239662; called by muse, mutect2, varscan2
- IMPDH2 | c.1234C>T p.R412C | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs779322486, COSV100455176, COSV58246414; called by muse, mutect2, varscan2
- LHX8 | c.247G>A p.V83M | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.822); catalogued as COSV99633912; called by muse, mutect2, varscan2
- PDE10A | c.1676C>T p.A559V | Missense Mutation (SNP) | VAF 38/105 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as rs1031927586, COSV100605227, COSV63098583; called by muse, mutect2, varscan2
- PRICKLE2 | c.514G>A p.G172R (on ENST00000295902; = p.G116R on NM_198859.4) | Missense Mutation (SNP) | VAF 28/94 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99897529; called by muse, mutect2, varscan2
- SORCS1 | c.338C>T p.A113V | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0); catalogued as COSV53864467; called by muse, mutect2
- USP31 | c.3417G>T p.R1139S | Missense Mutation (SNP) | VAF 28/73 reads (38%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.323); catalogued as COSV99565412; called by muse, mutect2, varscan2
- XIRP1 | c.2668G>A p.V890M | Missense Mutation (SNP) | VAF 11/21 reads (52%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as rs754187803, COSV61137398; called by muse, mutect2, varscan2
- PRKDC | c.9433A>T p.I3145L | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.063); called by muse, mutect2
- ACOT2 | c.1419T>C p.G473= | Silent (SNP) | VAF 30/111 reads (27%) | catalogued as COSV99469067; called by muse, mutect2, varscan2
- DNAI1 | c.441C>T p.D147= | Silent (SNP) | VAF 12/28 reads (43%) | catalogued as rs374753293; called by muse, mutect2, varscan2
- DTX2 | c.525A>G p.Q175= | Silent (SNP) | VAF 24/43 reads (56%) | catalogued as rs769857912, COSV100184666; called by muse, mutect2, varscan2
- RYR2 | c.1392C>T p.H464= | Silent (SNP) | VAF 8/26 reads (31%) | catalogued as COSV100771204; called by muse, mutect2, varscan2
